Somatic mutation profile of tumor specimen TCGA-AB-2935-03A (aliquot TCGA-AB-2935-03A-01W-0755-09) from TCGA case TCGA-AB-2935, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.7 years (24,349 days).
Specimen TCGA-AB-2935-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15ee51a4-aa54-479f-8903-a85d131b34c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2935-11A (Solid Tissue Normal), aliquot TCGA-AB-2935-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fdace44-9647-4d58-af44-90d48ea8af6b

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 14, Silent 6, Splice Site 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.3721C>T p.R1241* | Nonsense Mutation (SNP) | VAF 20/402 reads (5%) | hotspot (GDC flag); catalogued as rs137854562, CM000799, COSV62191467; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ADGRL4 | c.1618A>C p.S540R | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV100876367; called by muse, mutect2
- ANO3 | c.2183G>C p.G728A | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV56808675, COSV99884639; called by muse, mutect2, varscan2
- CAMK1 | c.350A>G p.D117G | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99844872; called by muse, mutect2
- CAMKV | c.1490G>A p.R497K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV56556884; called by muse, varscan2
- FREM2 | c.8862C>T p.D2954= | Splice Region (SNP) | VAF 57/205 reads (28%) | catalogued as COSV99750023; called by muse, mutect2, varscan2
- GJB3 | c.429C>G p.F143L | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99055558; called by muse, mutect2, varscan2
- KCNRG | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV100078497; called by muse, mutect2
- MOCOS | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.094); catalogued as rs182781411, COSV99733756; called by muse, mutect2, varscan2
- PPIC | c.425A>G p.N142S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs766984428; called by muse, mutect2, varscan2
- ADGRF5 | c.2119A>C p.K707Q | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.072); called by muse, mutect2
- ATRAID | c.424C>G p.P142A (on ENST00000611786; = p.P29A on NM_016085.5) | Missense Mutation (SNP) | VAF 4/99 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.717); called by muse, mutect2
- COG5 | c.2351G>C p.R784T (on ENST00000347053 / NM_001379512.1; = p.R805T on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2
- LEXM | c.1097C>A p.T366K | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.209); called by muse, mutect2
- MCTP1 | c.2611-1G>A p.X871_splice | Splice Site (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- PRKCI | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS13 | c.1473C>A p.G491= | Silent (SNP) | VAF 2/14 reads (14%) | called by muse, mutect2
- AKR1E2 | c.90G>A p.G30= | Silent (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- ALOX5 | c.1527C>T p.F509= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1161630564, COSV65551058; called by muse, mutect2, varscan2
- GIMAP4 | c.978C>T p.F326= | Silent (SNP) | VAF 11/251 reads (4%) | catalogued as rs1393875920, COSV55434847, COSV99750387; called by muse, mutect2
- GOLGA4 | c.645G>A p.E215= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV100729076; called by muse, mutect2
- TCERG1L | c.507C>A p.S169= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV64056464; called by muse, mutect2
